MMRF case MMRF_1485 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9a05992e-c8cf-4308-bcff-4583009d64de

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 152 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.2 years (29,277 days); ISS stage: II; Days to last known disease status: 152 days; Days to last follow up: 152 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.

Follow-up (2 entries)
- Days to follow up: -13 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 152.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Immunoglobulin M 0.18 g/L.
- Lactate Dehydrogenase 3 µkat/L.
- Platelets 174 ×10⁹/L.
- Calcium 2.35 mmol/L.
- Albumin 42 g/L.
- Leukocytes 5.7 ×10⁹/L.
- Blood Urea Nitrogen 13.9 mmol/L.
- M Protein 0.49 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 82.6 mg/dL.
- Hemoglobin 5.02 mmol/L.
- Total Protein 6.5 g/dL.
- Beta 2 Microglobulin 4.06 µg/mL.
- Glucose 5.45 mmol/L.
- Absolute Neutrophil 4.4 ×10⁹/L.
- Immunoglobulin A 4.07 g/L.
- Immunoglobulin G 3.1 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.692 mg/dL.
- Creatinine 104 µmol/L.

Other clinical attributes
- Day -13: Weight: 71 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Kidney Cancer.

Biospecimens (2 samples)
- Sample MMRF_1485_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1485_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
